Somatic mutation profile of cancer-model specimen HCM-WCMC-0753-C54-85A (3D Organoid, passage 14; aliquot HCM-WCMC-0753-C54-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0753-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.2 years (19,444 days).
Specimen HCM-WCMC-0753-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f3be978-9663-4e90-b6cd-a6b4c49e200b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0753-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-0753-C54-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcbd5fd7-f45a-4445-81ec-4fcd941e2224

The open-access MAF lists 52 somatic variants for this specimen: 44 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 6, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, 5'UTR 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 197/448 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 208/408 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs587783137, CM145772; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 178/419 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142650803; called by muse, mutect2, varscan2
- CASP10 | c.1237G>A p.E413K (on ENST00000272879 / NM_032974.5; = p.E370K on NM_001230.5) | Missense Mutation (SNP) | VAF 226/466 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780430275, COSV53777308; called by muse, mutect2, varscan2
- CCDC175 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 136/298 reads (46%) | catalogued as rs993905165, COSV55787304; called by muse, mutect2, varscan2
- MAP3K2 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs748193402, COSV61294473; called by muse, mutect2, varscan2
- MTMR3 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 158/333 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs760813550, COSV104405684, COSV60308227; called by muse, mutect2, varscan2
- MYO3A | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 152/340 reads (45%) | catalogued as COSV56323615; called by muse, mutect2, varscan2
- PCDH15 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as rs757431276; called by muse, mutect2, varscan2
- PCDHGA12 | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.041); catalogued as rs773899530, COSV99340665; called by muse, mutect2, varscan2
- POR | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 155/295 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67516263; called by muse, mutect2, varscan2
- PRAMEF14 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 246/542 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs771089877; called by muse, mutect2, varscan2
- PRSS38 | c.302G>C p.C101S | Missense Mutation (SNP) | VAF 139/272 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64541184; called by muse, mutect2, varscan2
- SI | c.3232C>T p.R1078W | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769259229, COSV52270933, COSV52283854; called by muse, varscan2
- SKIV2L | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 219/423 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs547774154; called by muse, mutect2, varscan2
- SLC4A2 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 177/417 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs201086697, COSV59657692; called by muse, mutect2, varscan2
- TAS2R39 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 140/299 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs749967220, COSV71470883; called by muse, mutect2, varscan2
- TGM2 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 168/337 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs943593932; called by muse, mutect2, varscan2
- TNRC6B | c.2516C>A p.S839* | Nonsense Mutation (SNP) | VAF 259/571 reads (45%) | catalogued as COSV57294492; called by muse, mutect2, varscan2
- ZNF316 | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 256/520 reads (49%) | SIFT deleterious, low confidence (0.01); catalogued as rs1251424280; called by muse, varscan2
- ANKS6 | c.1818C>A p.D606E | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ARID5B | c.1360_1363del p.E454Kfs*24 | Frame Shift Del (DEL) | VAF 245/270 reads (91%) | called by pindel, varscan2
- AURKAIP1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 216/472 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83B | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLRT1 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXA2 | c.642C>A p.N214K (on ENST00000377115 / NM_153675.3; = p.N220K on NM_021784.5) | Missense Mutation (SNP) | VAF 155/350 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPK | c.280_281del p.I94* | Frame Shift Del (DEL) | VAF 90/295 reads (31%) | called by pindel, varscan2
- MAP3K4 | c.1982G>A p.G661D | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MELK | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- PCM1 | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2
- PGAP4 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 220/422 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLPPR4 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 151/316 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- POLR1D | c.121A>T p.M41L | Missense Mutation (SNP) | VAF 23/463 reads (5%) | called by muse, mutect2
- PTEN | c.898dup p.I300Nfs*3 | Frame Shift Ins (INS) | VAF 234/325 reads (72%) | called by mutect2, pindel, varscan2
- PTPRQ | c.5125C>G p.P1709A (on ENST00000616559; = p.P1667A on NM_001145026.2) | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.5278dup p.S1760Kfs*17 | Frame Shift Ins (INS) | VAF 119/304 reads (39%) | called by mutect2, pindel, varscan2
- S100A14 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SHROOM3 | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 242/488 reads (50%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA3 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- TAF1 | c.3183_3197del p.E1061_T1065del (on ENST00000373790 / NM_138923.4; = p.E1082_T1086del on NM_004606.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 124/299 reads (41%) | called by mutect2, varscan2
- TIAL1 | c.342del p.K114Nfs*15 | Frame Shift Del (DEL) | VAF 268/371 reads (72%) | called by mutect2, pindel, varscan2
- TRIM49 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 136/381 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- VNN1 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF226 | c.153del p.F52Sfs*8 | Frame Shift Del (DEL) | VAF 131/305 reads (43%) | called by mutect2, pindel, varscan2
- CASR | c.960C>T p.F320= | Silent (SNP) | VAF 207/412 reads (50%) | catalogued as rs753011255, COSV56133741; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT4 | c.3324C>T p.Y1108= | Silent (SNP) | VAF 135/300 reads (45%) | called by muse, mutect2, varscan2
- HEPH | c.3363C>T p.L1121= (on ENST00000343002; = p.L854= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 283/598 reads (47%) | catalogued as rs766265686, COSV57963845; called by muse, mutect2, varscan2
- IFT172 | c.5004C>T p.G1668= | Silent (SNP) | VAF 217/483 reads (45%) | catalogued as rs761028024; called by muse, mutect2, varscan2
- TNFRSF8 | c.894C>T p.A298= | Silent (SNP) | VAF 204/411 reads (50%) | called by muse, mutect2, varscan2
- UNC13A | c.5064G>A p.K1688= | Silent (SNP) | VAF 205/418 reads (49%) | catalogued as rs753658542; called by muse, mutect2, varscan2
- B4GALT2 | c.-21G>A | 5'UTR (SNP) | VAF 224/495 reads (45%) | catalogued as rs375329179; called by muse, mutect2, varscan2
- CBARP | c.1214+107C>T | Intron (SNP) | VAF 285/615 reads (46%) | catalogued as rs1178738551; called by muse, mutect2, varscan2
